Surgical pathology report (de-identified scan), TCGA case TCGA-VD-AA8Q, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-AA8Q-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology

HISTOPATHOLOGY

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]		Sex [REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

SPECIMEN

RIGHT EYE. Diagnostic and prognostic.

CLINICAL DETAILS

Right eye choroidal tumour. Right enucleation of globe.
Measurements: 13.90 x 12.20 x (10.07)mm.

MACROSCOPIC DESCRIPTION

A fresh intact right globe

Dimensions: Axial 26mm Horizontal 24.5mm Vertical 24mm.

Cornea: Horizontal 12mm Vertical 11mm.

Optic Nerve - flush

Pupil - regular

Angle normal deptn.

?Engorged vortex veins inferiorly.

On transillumination, a large shadow is seen on the medial side with a maximum diameter of 17mm.

Plane of section: Horizontal

Intraocular description:

On opening, a solitary dome shaped pigmented choroidal mass is seen.

Tumour SizeLBD 12mmHeight 10mm.

MICROSCOPY

Sections confirm a deeply pigmented choroidal melanoma consisting predominantly of spindle cells. Tumour cells express Melan-A and HSP 27 (score 2). The number of mitosis is small, approximately 1/40 high power fields. Closed loops are not present in the planes of sections. The lymphocytic

*ICD-O-3
Melanoma, spindle cell, type B 8774/3
Site: (R)Choroid C69.3
7/25/2014*

Reported:

Pathologist: [REDACTED]

Electronically Verified [REDACTED]

[page 2 of 3]
Department of Pathology

Page 2 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

infiltrate within the tumour is minimal. Scattered macrophages are present. Tumour necrosis is not seen. There is no tumour extension through the sclera, optic nerve or vortex veins examined. Tumour cells are not seen at the resection margins.

Elsewhere, the cornea shows oedema in its basal cell layers. The anterior chamber angles are open and the anterior chamber is deep. The iris shows no significant abnormality but the ciliary body appears atrophic with hyalinisation of ciliary processes. The lens shows subcapsular degenerative changes. Retina overlying the tumour is slightly atrophic.

DIAGNOSIS

Right eye, enucleation: Choroidal melanoma of predominantly spindle cell type.

SUMMARY

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	2= Spindle B
CT LOOPS	1= No closed loops
NECROSIS	No
PIGMENTATION	Yes
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	1/40 HPF
DIFFUSE MELANOMA	No
SPREAD	1= No
CLEARANCE	2= Adequate
HSP-27 POSITIVITY	2= 21-70%
LARGE DIAMETER	12 mm
THICKNESS	10 mm

Reported:

Pathologist: [REDACTED]

Electronically Verified [REDACTED]

[page 3 of 3]
Department of Pathology

Page 3 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]	

This Copy For: [REDACTED]

COMMENT

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow in due course.

SUPPLEMENTARY REPORT - MLPA

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED], which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

normal chromosome 1p,
disomy 3,
normal chromosome 6
and normal chromosome 8.

Taken together, these molecular data would place the patient in the low risk group with respect to the development of metastatic melanoma.

Consideration of clinical features of the tumour is, however, also required.

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

Source: NCI Genomic Data Commons file 323a3b25-2c00-4e1a-a439-e6858d7fe892 (TCGA-VD-AA8Q.BA6A5CAA-0D65-4F4F-A15B-EB0D4ABC1D87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).